Somatic mutation profile of tumor specimen ALCH-ADR8-TTP1-A (aliquot ALCH-ADR8-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADR8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.0 years (16,080 days).
Specimen ALCH-ADR8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f846071c-d63d-44a9-9c09-5382e9b55c31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADR8-NB1-A (Blood Derived Normal), aliquot ALCH-ADR8-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76709035-c1b1-4981-9134-8ffe3633bc1a

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 1, Intron 1, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 136/671 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC231657.3 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1557083331; called by muse, mutect2
- CNGA2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569428488, COSV61705761; called by muse, mutect2, varscan2
- CNTLN | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV52065850; called by muse, mutect2, varscan2
- LAMC3 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 166/884 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs777086759, COSV63090346; called by muse, mutect2, varscan2
- PCDHA7 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV65347547, COSV65348243; called by muse, mutect2
- TEX14 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs201818573; called by muse, mutect2, varscan2
- TTN | c.83657G>T p.R27886I (on ENST00000591111; = p.R20462I on NM_003319.4) | Missense Mutation (SNP) | VAF 150/679 reads (22%) | PolyPhen possibly damaging (0.777); catalogued as COSV100634760; called by muse, mutect2, varscan2
- UNC80 | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55890143; called by muse, mutect2, varscan2
- ZNF189 | c.1535A>G p.Y512C | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766493070, COSV52275116; called by muse, mutect2, varscan2
- ACSBG1 | c.1767G>A p.M589I | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- B4GALNT3 | c.1943T>A p.L648Q | Missense Mutation (SNP) | VAF 107/594 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- DNAJC2 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IFT80 | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 75/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MITF | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NCOA6 | c.392-1G>A p.X131_splice | Splice Site (SNP) | VAF 60/262 reads (23%) | called by mutect2, varscan2
- OR13C9 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ZNF660 | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LAMB3 | c.2328G>A p.S776= | Silent (SNP) | VAF 36/678 reads (5%) | catalogued as rs139058862; called by muse, mutect2
- LVRN | c.1311C>T p.N437= | Silent (SNP) | VAF 44/312 reads (14%) | catalogued as rs758335122; called by muse, varscan2
- NPAP1 | c.2976A>T p.G992= | Silent (SNP) | VAF 68/458 reads (15%) | called by muse, mutect2, varscan2
- OLFML2B | c.1086C>T p.S362= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as rs768981145, COSV54201029; called by muse, mutect2, varscan2
- PCDH10 | c.2523C>T p.S841= | Silent (SNP) | VAF 69/326 reads (21%) | called by muse, mutect2, varscan2
- TULP1 | c.1233C>T p.N411= | Silent (SNP) | VAF 76/520 reads (15%) | catalogued as rs377376210; called by muse, mutect2, varscan2
- AC018563.1 | n.254C>T | RNA (SNP) | VAF 48/332 reads (14%) | called by muse, mutect2, varscan2
- CT83 | c.-12C>T | 5'UTR (SNP) | VAF 77/298 reads (26%) | catalogued as COSV64141260; called by muse, mutect2, varscan2
- POMT1 | c.428-14C>T | Intron (SNP) | VAF 56/310 reads (18%) | called by muse, mutect2, varscan2
